Somatic mutation profile of tumor specimen TARGET-40-NAAGKM-01A (aliquot TARGET-40-NAAGKM-01A-01D) from TARGET case TARGET-40-NAAGKM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.1 years (4,788 days).
Specimen TARGET-40-NAAGKM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45a68ac4-8a15-4f55-9bbe-c8335cb0e82d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGKM-10B (Blood Derived Normal), aliquot TARGET-40-NAAGKM-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfc21069-88ba-476f-a342-7cb5e18faf68

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 19/30 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VWDE | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1199170806; called by muse, mutect2, varscan2
- ITGAV | c.2637G>A p.G879= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- KIF13A | c.595T>C p.L199= | Silent (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
